Gene-level copy-number profile of tumor specimen TCGA-BR-8060-01A from TCGA case TCGA-BR-8060, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 75.5 years (27,561 days).
Specimen TCGA-BR-8060-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.6af88792-2140-478e-b37d-e6b01552a176.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8060-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/99731e10-67b8-4736-97d6-6a35e3ebc9d1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 931; copy number 2: 24,881; copy number 3: 23,159; copy number 4: 5,646; copy number 5: 2,073; copy number 6: 1,575; copy number 7: 572; copy number 8: 146; copy number 9: 301; copy number 10: 132; copy number 11: 10; copy number 12: 26; copy number 13: 9; copy number 15: 21; copy number 17: 52; copy number 18: 25; copy number 19: 8; copy number 20: 122; copy number 22: 20; copy number 23: 22; copy number 28: 33; copy number 32: 17; copy number 44: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8060-01A-11D-2338-01): tumor purity 0.63, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,314,246–10,612,723, 8 genes (within-gene range 0–2): PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P.
- chr11:98,938,912–101,129,813, 10 genes (within-gene range 0–1): AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR.
- chr16:6,380,476–7,004,112, 7 genes: AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,521 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:197,293,878–197,573,323, 8 genes, copy number 13: MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1.
- chr3:197,580,344–197,580,629, 1 gene, copy number 13: AC132008.1.
- chr5:58,198–31,329,146, 460 genes, copy number 7–9 (broad region; genes not listed).
- chr5:38,025,568–45,895,970, 122 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:31,394,289–32,407,763, 116 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr6:106,045,423–106,325,791, 1 gene, copy number 11 (within-gene range 4–11): ATG5.
- chr6:106,271,634–107,459,564, 24 genes, copy number 11–23 (within-gene range 4–23): U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr8:9,899,871–19,084,730, 203 genes, copy number 15–28 (within-gene range 3–28) (broad region; genes not listed).
- chr9:68,328,308–68,531,061, 1 gene, copy number 17 (within-gene range 3–18): PGM5.
- chr9:68,393,881–76,362,975, 94 genes, copy number 12–22 (within-gene range 2–22) (broad region; genes not listed).
- chr9:76,385,526–77,020,953, 14 genes, copy number 10: RFK, RPSAP9, GCNT1, H3P32, PPIAP87, PRUNE2, PCA3, AL359314.1, AL390239.1, AL353637.2, DNAJB5P1, LYPLA2P3, AL353637.1, FOXB2.
- chr13:37,632,063–37,874,444, 3 genes, copy number 8: TRPC4, RNA5SP26, AL356495.1.
- chr13:42,339,188–42,608,013, 3 genes, copy number 8 (within-gene range 4–8): LINC02341, FABP3P2, TNFSF11.
- chr16:89,560,677–89,920,973, 18 genes, copy number 9: RPL13, SNORD68, CPNE7, DPEP1, CHMP1A, SPATA33, AC010538.1, CDK10, LINC02166, SPATA2L, VPS9D1, VPS9D1-AS1, ZNF276, FANCA, SPIRE2, TCF25, AC092143.3, MC1R.
- chr18:47,390–15,330,282, 376 genes, copy number 9–10 (broad region; genes not listed).
- chr19:28,294,093–29,525,752, 28 genes, copy number 9–32 (within-gene range 2–32): AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3.
- chr19:29,665,459–30,038,181, 13 genes, copy number 19–44: PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1.
- chr19:30,228,290–30,713,538, 3 genes, copy number 8 (within-gene range 2–8): ZNF536, AC011504.1, AC011478.1.
- chr20:22,220,554–22,886,068, 12 genes, copy number 7: AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4.
- chr20:49,503,874–50,176,676, 21 genes, copy number 8: PTGIS, B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273.

Autosomal genes at a single copy (total copy number 1): 931. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
